Somatic mutation profile of tumor specimen ALCH-B2SY-TTP1-A (aliquot ALCH-B2SY-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2SY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.9 years (24,797 days).
Specimen ALCH-B2SY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00085ead-4d4b-4d28-828d-7c2c2e370aa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SY-NB1-A (Blood Derived Normal), aliquot ALCH-B2SY-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b35e403-9c22-4314-9a19-bdaec52f4bd1

The open-access MAF lists 553 somatic variants for this specimen: 379 protein-altering or splice-affecting, 129 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 341, Silent 129, Nonsense Mutation 25, Intron 16, RNA 15, Splice Site 8, 5'UTR 6, 3'UTR 4, Splice Region 3, 5'Flank 3, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 37/445 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 55/558 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.277del p.L93Cfs*30 | Frame Shift Del (DEL) | VAF 20/148 reads (14%) | catalogued as rs1567556123, COSV53525400; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZAP70 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as rs869025224, CM161395, COSV53852530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4510G>A p.E1504K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as rs190370456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADIPOR1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV100579497, COSV61851379; called by muse, mutect2
- AGO3 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs750071028; called by muse, mutect2, varscan2
- AKAP13 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV63450722; called by muse, mutect2, varscan2
- ALK | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV66581185; called by muse, mutect2, varscan2
- ANKLE1 | c.875C>T p.P292L (on ENST00000394458; = p.P238L on NM_152363.6) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV63920328; called by muse, mutect2, varscan2
- ANO2 | c.2476C>A p.P826T (on ENST00000356134 / NM_001278597.3; = p.P830T on NM_001278596.3) | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100502649, COSV59016421; called by muse, mutect2, varscan2
- AP1G2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 72/575 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as rs754721186; called by muse, mutect2, varscan2
- ARFRP1 | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 26/338 reads (8%) | catalogued as rs751595682; called by muse, mutect2
- ARHGAP44 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs1465728888; called by muse, mutect2
- ATG10 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1160379912; called by muse, mutect2
- ATP10D | c.883+1G>T p.X295_splice | Splice Site (SNP) | VAF 14/265 reads (5%) | catalogued as COSV56714937; called by muse, mutect2
- BAIAP3 | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs372361431; called by muse, mutect2
- BAZ2B | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV58597002; called by muse, mutect2
- BOC | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs149038528, COSV104383250; called by muse, mutect2
- C22orf31 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 42/915 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV53310897; called by muse, mutect2
- CABP5 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138142491; called by muse, mutect2, varscan2
- CACNA1S | c.5198G>C p.R1733T | Missense Mutation (SNP) | VAF 30/505 reads (6%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV62937697; called by muse, mutect2
- CACNA1S | c.3217G>C p.E1073Q | Missense Mutation (SNP) | VAF 51/692 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62938008; called by muse, mutect2
- CAVIN2 | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1218345828, COSV58424152; called by muse, mutect2
- CCDC102B | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 34/438 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1422255045; called by muse, mutect2
- CDH4 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848531, COSV64647760; called by muse, mutect2, varscan2
- CELSR2 | c.7925C>T p.S2642L | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs1200260481, COSV54776223; called by muse, mutect2
- CFAP43 | c.2005A>T p.T669S | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1291529033; called by muse, mutect2
- CHD5 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.038); catalogued as COSV52408244; called by muse, mutect2
- CHD9 | c.7600G>A p.E2534K (on ENST00000398510 / NM_001382353.1; = p.E2518K on NM_025134.7) | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.709); catalogued as COSV54611417; called by muse, mutect2
- CLDN25 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71620491; called by muse, mutect2
- CNGB3 | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183126; called by muse, mutect2
- COMMD8 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV67500453; called by muse, mutect2
- CTNNA2 | c.2684G>C p.G895A (on ENST00000402739 / NM_001282597.3; = p.G847A on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as COSV100560085; called by muse, mutect2
- DCAF6 | c.2074G>C p.E692Q (on ENST00000312263 / NM_001349778.1; = p.E712Q on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100394278; called by muse, mutect2
- DDX23 | c.2240-1G>C p.X747_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV56399411; called by muse, varscan2
- DEPDC7 | c.850A>G p.I284V (on ENST00000241051 / NM_001077242.2; = p.I275V on NM_139160.2) | Missense Mutation (SNP) | VAF 34/553 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1301864954; called by muse, mutect2
- DMD | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 40/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072996, COSV55873472; called by muse, mutect2
- DSG4 | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 42/728 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV57397302; called by muse, mutect2
- DUS1L | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57648046, COSV57651082; called by muse, mutect2
- ERBB3 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 98/925 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); catalogued as COSV57248809, COSV57255244; called by muse, mutect2, varscan2
- F8 | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557278285, CM062670, COSV64276626; called by muse, mutect2
- FAM110D | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV65321899; called by muse, varscan2
- FAM222B | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs757782771; called by muse, mutect2, varscan2
- FAM71F2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 63/591 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs553880583; called by muse, mutect2, varscan2
- FFAR1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 85/641 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.467); catalogued as rs143187042, COSV99322802; called by muse, mutect2, varscan2
- FZD9 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs1554563451; called by muse, mutect2, varscan2
- GBA | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 178/989 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV59170739; called by muse, mutect2, varscan2
- GLI3 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 54/1032 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV67885445; called by muse, mutect2
- GOLPH3 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 31/497 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs757857131; called by muse, mutect2
- HDHD2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as rs755358634; called by muse, mutect2
- HS3ST3A1 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as rs949091637; called by muse, mutect2, varscan2
- HTATSF1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV54477955; called by muse, mutect2
- KCNJ8 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99557356; called by muse, mutect2
- KCNK10 | c.1376A>G p.K459R | Missense Mutation (SNP) | VAF 86/920 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751205780; called by muse, mutect2
- KEAP1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50270031; called by muse, mutect2, varscan2
- KIF26B | c.5695G>A p.E1899K | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs763990399, COSV63646264; called by muse, mutect2
- KIF5A | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 63/702 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1422332328, COSV54055787; called by muse, mutect2
- KIRREL2 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs199552023, COSV52876644; called by muse, mutect2, varscan2
- KLF17 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779440513, COSV64855913; called by muse, mutect2
- KLHL1 | c.1015-1G>T p.X339_splice | Splice Site (SNP) | VAF 18/126 reads (14%) | catalogued as COSV64771130, COSV64776196; called by muse, mutect2
- KMT2B | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as rs370754915; called by muse, mutect2, varscan2
- KMT2C | c.3638G>T p.S1213I | Missense Mutation (SNP) | VAF 44/685 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100071781; called by muse, mutect2
- KRT72 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV53374170; called by muse, mutect2
- LAMB4 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs780322560, COSV99225547; called by muse, mutect2
- LCE1A | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.957); catalogued as COSV58727895; called by muse, mutect2, varscan2
- LILRB4 | c.1000G>T p.V334L (on ENST00000391733 / NM_001278428.3; = p.V333L on NM_001278426.3) | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV54408803; called by muse, mutect2
- LINS1 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 105/612 reads (17%) | catalogued as COSV59077834, COSV59080366; called by muse, mutect2, varscan2
- LPAR4 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868338754, COSV101425097; called by muse, mutect2, varscan2
- LST1 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 45/714 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV53002816; called by muse, mutect2
- MAGEE1 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63910158; called by muse, mutect2
- MAP3K15 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.431); catalogued as COSV58836496; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MCRS1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV59459208; called by muse, mutect2
- METTL25 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 30/405 reads (7%) | catalogued as rs1463145191; called by muse, mutect2
- MGAT4C | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1222715246, COSV59830124, COSV59831777; called by muse, mutect2
- MICAL3 | c.5808A>C p.E1936D | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52811652; called by muse, mutect2
- MROH2A | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1168426883; called by muse, mutect2
- MRPL28 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs1259865383; called by muse, mutect2
- MYO7A | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1250301241, COSV68683267, COSV68686873; called by muse, mutect2
- MYO7A | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 36/421 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs772795781; called by muse, mutect2
- NAV1 | c.1230G>T p.W410C | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1165250322; called by muse, mutect2, varscan2
- NBPF1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 65/1869 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs761369854, COSV101236055, COSV101236686; called by muse, mutect2
- NCAM1 | c.2020C>A p.L674M (on ENST00000316851 / NM_181351.5; = p.L664M on NM_000615.7) | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57514350; called by muse, mutect2, varscan2
- NCOA3 | c.3379C>G p.H1127D | Missense Mutation (SNP) | VAF 48/741 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59067057; called by muse, mutect2
- NFATC3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60475912; called by muse, varscan2
- NLRP3 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 75/777 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs147876634; called by muse, mutect2, varscan2
- NPAP1 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100274534, COSV61510472; called by mutect2, varscan2
- NPFFR1 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 66/595 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53334825; called by muse, mutect2, varscan2
- NTNG1 | c.998A>T p.Y333F | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs773006154; called by muse, mutect2
- OR1G1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs139528916; called by muse, mutect2
- OR1S1 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770476205; called by muse, mutect2, varscan2
- OR5I1 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56887030; called by muse, mutect2, varscan2
- OR6Q1 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376001783; called by muse, mutect2, varscan2
- OSMR | c.2543C>G p.S848C | Missense Mutation (SNP) | VAF 39/583 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as rs1561416545; called by muse, mutect2
- PAK3 | c.532G>T p.E178* (on ENST00000262836 / NM_001324328.2; = p.E163* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 69/724 reads (10%) | catalogued as COSV53278844; called by muse, mutect2, varscan2
- PALLD | c.2530C>G p.Q844E (on ENST00000505667 / NM_001166108.2; = p.Q827E on NM_016081.4) | Missense Mutation (SNP) | VAF 23/439 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV99824098; called by muse, mutect2
- PAPPA2 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV100867126; called by muse, mutect2
- PCLO | c.6277G>C p.E2093Q | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV61631444; called by muse, mutect2
- PDHA2 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293790541, COSV54780540; called by muse, mutect2
- PELI2 | c.496A>T p.I166L | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs750175175; called by muse, mutect2
- PKD1L1 | c.4706A>C p.N1569T | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV99219685; called by muse, mutect2
- PKP1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 44/606 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs528712537, COSV99825286; called by muse, mutect2
- PLEKHG4B | c.2200C>T p.Q734* (on ENST00000283426; = p.Q1090* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 26/754 reads (3%) | catalogued as COSV52053983; called by muse, mutect2
- PLSCR1 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs745943253, COSV100678345; called by muse, mutect2, varscan2
- POT1 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV104423881, COSV62930232; called by muse, mutect2
- PRDM9 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 64/815 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.264); catalogued as COSV57004571; called by muse, mutect2
- PRL | c.75C>A p.S25R | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.339); catalogued as COSV60593474; called by muse, mutect2
- PRPF38B | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 46/626 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV64224092; called by muse, mutect2
- PRUNE2 | c.8488G>A p.E2830K | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795871; called by muse, mutect2
- PSG2 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 68/860 reads (8%) | catalogued as COSV100283682; called by muse, mutect2
- PSG8 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 75/538 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.348); catalogued as COSV60612570; called by muse, mutect2
- PSG8 | c.763A>T p.K255* | Nonsense Mutation (SNP) | VAF 71/514 reads (14%) | catalogued as rs1159808386; called by muse, mutect2
- RASAL3 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 29/433 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs199723638, COSV59140658; called by muse, mutect2
- RBM10 | c.576+1G>T p.X192_splice | Splice Site (SNP) | VAF 116/1111 reads (10%) | catalogued as COSV61311810; called by muse, mutect2, varscan2
- RD3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs142307843; called by muse, mutect2, varscan2
- RGS22 | c.1487A>T p.E496V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1345882243; called by muse, mutect2
- SDF4 | c.892-4G>T | Splice Region (SNP) | VAF 32/251 reads (13%) | catalogued as rs745821280; called by muse, mutect2, varscan2
- SDK1 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV101268860; called by muse, mutect2
- SETBP1 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 40/817 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV56341232; called by muse, mutect2
- SEZ6L | c.1683G>A p.A561= | Splice Region (SNP) | VAF 12/103 reads (12%) | catalogued as rs199961565, COSV50662660, COSV50676296; called by muse, mutect2
- SH2D3C | c.616G>A p.E206K (on ENST00000314830 / NM_170600.3; = p.E49K on NM_005489.4) | Missense Mutation (SNP) | VAF 50/679 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs750630588; called by muse, mutect2
- SHARPIN | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV100010617; called by muse, mutect2
- SLC12A1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV66795672; called by muse, mutect2
- SLC28A3 | c.1867C>T p.H623Y | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV66154217; called by muse, mutect2
- SLIT2 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99883761, COSV99887190; called by muse, mutect2
- SMC1A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 40/870 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV59131610; called by muse, mutect2
- SNRNP48 | c.190C>G p.H64D | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242164887; called by muse, mutect2, varscan2
- SRPK2 | c.1712C>A p.A571E | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61959933; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 30/667 reads (4%) | PolyPhen probably damaging (0.952); catalogued as COSV99398439; called by muse, mutect2
- SYT3 | c.1410C>A p.Y470* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs202126818; called by muse, mutect2, varscan2
- TBL1XR1 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.123); catalogued as COSV70503192; called by muse, mutect2, varscan2
- TCAF2 | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 88/884 reads (10%) | catalogued as rs551428464; called by muse, mutect2
- TCP11L2 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100135215; called by muse, mutect2
- THSD7B | c.3708G>C p.Q1236H (on ENST00000272643; = p.Q1234H on NM_001316349.2) | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); catalogued as COSV55671140; called by muse, mutect2
- TNFRSF14 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.488); catalogued as COSV63186054; called by muse, mutect2
- TRIM22 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66090141; called by muse, mutect2
- TTN | c.53062G>C p.E17688Q (on ENST00000591111; = p.E10264Q on NM_003319.4) | Missense Mutation (SNP) | VAF 13/250 reads (5%) | PolyPhen benign (0.329); catalogued as rs975610705, COSV100615946; called by muse, mutect2
- TTN | c.27898G>C p.E9300Q (on ENST00000591111; = p.E8373Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/294 reads (7%) | PolyPhen benign (0.011); catalogued as rs144025230; called by muse, mutect2
- TXLNG | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV101200562; called by muse, mutect2, varscan2
- UCN2 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1490816690; called by muse, mutect2
- UGGT2 | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 44/483 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV65078432; called by muse, mutect2
- UGT1A5 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.1); catalogued as rs1219842752; called by muse, mutect2
- UGT2B10 | c.1439A>T p.H480L | Missense Mutation (SNP) | VAF 70/736 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV55321194; called by muse, mutect2
- USP31 | c.2671A>T p.S891C | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV54851981; called by muse, mutect2, varscan2
- XPNPEP2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.559); catalogued as rs756494472, COSV64369034; called by muse, mutect2, varscan2
- ZFC3H1 | c.4600G>A p.E1534K | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66431394; called by muse, mutect2
- ZFR | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1035189676; called by muse, mutect2, varscan2
- ZNF208 | c.2486G>T p.G829V | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV68102366, COSV68109755; called by muse, varscan2
- ZNF397 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1569044184; called by muse, mutect2
- ZNF777 | c.2051G>C p.R684P | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56096521; called by muse, mutect2
- A4GNT | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 53/729 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.245); called by muse, mutect2
- ABCA5 | c.1645G>C p.D549H | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- ABHD15 | c.806G>C p.R269P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, varscan2
- ACSM5 | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 62/942 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- ACSM5 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 63/952 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.612); called by muse, mutect2
- ACTR6 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- ADCY1 | c.2660A>G p.N887S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); called by muse, mutect2
- ADCY10 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 50/820 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCY6 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGB | c.2487C>A p.F829L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL4 | c.793A>T p.M265L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2
- ADORA1 | c.185T>A p.V62D | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADRB1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AFF2 | c.2589G>C p.K863N | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.631); called by muse, mutect2
- AHCTF1 | c.6281G>T p.R2094L (on ENST00000366508; = p.R2068L on NM_015446.5) | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AHR | c.2368C>G p.P790A | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); called by muse, mutect2
- AKAP9 | c.4770G>C p.M1590I | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ALPK2 | c.2998C>G p.Q1000E | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2
- AMMECR1 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 30/475 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 24/345 reads (7%) | called by muse, mutect2
- ANKRA2 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 38/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ANOS1 | c.1988C>G p.S663C | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2
- APPBP2 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 61/1134 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2
- ARHGAP4 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- ARHGEF33 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ARID4B | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.34); called by muse, mutect2
- ASPA | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 51/512 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2
- ASPM | c.9122G>C p.R3041T | Missense Mutation (SNP) | VAF 30/686 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP10B | c.1490G>C p.R497T | Missense Mutation (SNP) | VAF 49/413 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ATP6V0A4 | c.1683C>G p.F561L | Missense Mutation (SNP) | VAF 44/657 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- ATP9A | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 37/439 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- BGN | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 61/490 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- BHLHE22 | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, varscan2
- BIRC6 | c.4969C>T p.Q1657* | Nonsense Mutation (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- BIRC6 | c.6934G>T p.E2312* | Nonsense Mutation (SNP) | VAF 39/1045 reads (4%) | called by muse, mutect2
- BPIFA1 | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); called by muse, mutect2
- C11orf42 | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 72/561 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C3orf20 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 31/532 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.234); called by muse, mutect2
- CACNA1E | c.3810G>C p.K1270N | Missense Mutation (SNP) | VAF 34/573 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACUL1 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.026); called by muse, mutect2
- CADPS | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CALHM1 | c.669T>A p.Y223* | Nonsense Mutation (SNP) | VAF 39/482 reads (8%) | called by muse, mutect2
- CCDC88B | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CENATAC | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- CHD1L | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.025); called by muse, mutect2
- CHRNB1 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 92/949 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2
- COG5 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 65/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL12A1 | c.8178G>T p.R2726S | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- COL12A1 | c.8177G>T p.R2726M | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL25A1 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COMMD1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2
- COQ4 | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- CPSF1 | c.2839G>T p.G947C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CREM | c.890G>T p.R297M (on ENST00000429130; = p.R252M on NM_181571.3) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CRX | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CSMD3 | c.5923G>C p.A1975P (on ENST00000297405 / NM_001363185.1; = p.A1871P on NM_052900.3) | Missense Mutation (SNP) | VAF 35/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- CUL2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2
- CUX2 | c.4378G>A p.E1460K | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- CYLC1 | c.1241A>G p.E414G | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.426); called by muse, varscan2
- DCAF8L1 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- DDN | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- DHRS2 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DOCK1 | c.3655T>C p.Y1219H | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- DYNC2H1 | c.9805C>T p.L3269F | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2
- EML4 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2
- EYS | c.5133G>T p.M1711I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); called by muse, mutect2
- EYS | c.4739C>A p.S1580Y | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2
- EZHIP | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- F13A1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 50/511 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- FAM13C | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 28/324 reads (9%) | called by muse, mutect2
- FAM43B | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, varscan2
- FAM47B | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FANCA | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- FCRL5 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- FIZ1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.019); called by muse, mutect2
- FLNA | c.7441G>A p.E2481K (on ENST00000369850 / NM_001110556.2; = p.E2473K on NM_001456.3) | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- FOXA2 | c.662C>G p.P221R (on ENST00000377115 / NM_153675.3; = p.P227R on NM_021784.5) | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- FOXD4 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 22/702 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- FOXG1 | c.975G>C p.L325F | Missense Mutation (SNP) | VAF 49/640 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- FRMPD3 | c.1885T>A p.S629T | Missense Mutation (SNP) | VAF 64/662 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2
- GAK | c.3072G>A p.M1024I | Missense Mutation (SNP) | VAF 25/550 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- GALR1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2
- GBF1 | c.3592G>C p.E1198Q (on ENST00000369983 / NM_001377137.1; = p.E1197Q on NM_004193.3) | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); called by muse, mutect2
- GDPD4 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- GIGYF1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- GK | c.78G>C p.L26F | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2
- GLB1L2 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GLI2 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLRB | c.529T>A p.L177I | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- GLYAT | c.775T>A p.F259I | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.124); called by muse, mutect2
- GPD1 | c.757T>A p.L253M | Missense Mutation (SNP) | VAF 84/950 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2
- GPR179 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GPR87 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2
- GUCY2F | c.3287G>A p.R1096K | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- HCRTR2 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- HFM1 | c.2782_2812+13del p.X928_splice | Splice Site (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel
- HGH1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGH1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 71/886 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.169); called by muse, mutect2
- HMGB4 | c.147G>C p.W49C | Missense Mutation (SNP) | VAF 27/452 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV3D-11 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 52/908 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2
- IHH | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL10 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 76/1131 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2
- IL20RB | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 29/563 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- INPP4B | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- INPP4B | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- INTS13 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- IRAK1 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); called by muse, mutect2
- IRF4 | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JUP | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 30/590 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- KIF26B | c.3369G>T p.E1123D | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF4A | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.66); called by muse, mutect2
- KLK15 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2
- KRTAP2-2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.915); called by muse, varscan2
- LCOR | c.2832G>C p.E944D | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.22); called by muse, mutect2
- LMOD2 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 42/539 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, mutect2
- LRRTM1 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LTBP1 | c.1337C>A p.S446Y (on ENST00000404816 / NM_206943.4; = p.S120Y on NM_000627.4) | Missense Mutation (SNP) | VAF 58/652 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2
- MBOAT4 | c.38C>G p.S13W | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- MCM9 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- MRC1 | c.3112C>A p.P1038T | Missense Mutation (SNP) | VAF 38/457 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- MS4A12 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MXRA5 | c.8222C>A p.P2741Q | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYRIP | c.2248C>G p.H750D | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); called by muse, mutect2
- NLRP8 | c.1708G>T p.A570S | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- NOS2 | c.651T>G p.C217W | Missense Mutation (SNP) | VAF 87/600 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH3 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NPHS2 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 62/716 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- NPHS2 | c.474C>A p.C158* | Nonsense Mutation (SNP) | VAF 66/714 reads (9%) | called by muse, mutect2
- OLFML2A | c.300T>G p.C100W | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2B11 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- OR2M7 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 50/664 reads (8%) | called by muse, mutect2
- OR2T34 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR52R1 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5F1 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- OR8I2 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OXER1 | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- OXR1 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.149); called by muse, mutect2
- PALM2AKAP2 | c.761T>A p.L254Q (on ENST00000259318 / NM_001136562.3; = p.L485Q on NM_007203.5) | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAXIP1 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 56/741 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDH15 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- PCDHGA8 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDHA2 | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDIA6 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 22/358 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- PELI2 | c.211A>C p.I71L | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHEX | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 72/724 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.094); called by muse, mutect2
- POLG2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- PPAT | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R12B | c.2216C>G p.S739* | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- PPP1R16B | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 36/560 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PPP6R2 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PRKDC | c.1327A>T p.I443L | Missense Mutation (SNP) | VAF 20/508 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2
- PRUNE2 | c.4568C>T p.P1523L | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPDC1 | c.1220A>C p.Q407P (on ENST00000375360 / NM_177995.3; = p.Q459P on NM_152422.4) | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- PTPRC | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 57/554 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB12 | c.227-2A>G p.X76_splice | Splice Site (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- RABL2B | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 50/755 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2
- RAP1B | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RB1CC1 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RGS12 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.053); called by muse, mutect2
- RIN2 | c.1660A>C p.S554R (on ENST00000255006 / NM_001242581.1; = p.S505R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/740 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RNF165 | c.601T>C p.S201P | Missense Mutation (SNP) | VAF 34/427 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.304); called by muse, mutect2
- RPS6KA6 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- RTL1 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, varscan2
- RUNX1T1 | c.966C>A p.D322E (on ENST00000265814 / NM_001198628.1; = p.D295E on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR2 | c.4012G>T p.D1338Y | Missense Mutation (SNP) | VAF 82/531 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- RYR2 | c.14234A>T p.D4745V | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SAE1 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.271); called by muse, mutect2
- SALL2 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.169); called by muse, mutect2
- SAMD5 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCUBE1 | c.2258C>A p.T753N | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2
- SEPTIN6 | c.882C>A p.H294Q | Missense Mutation (SNP) | VAF 60/704 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SF3B4 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); called by muse, mutect2
- SGCZ | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); called by muse, mutect2
- SHANK2 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SLC25A39 | c.354G>T p.E118D (on ENST00000377095 / NM_001143780.3; = p.E110D on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A2 | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 57/534 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLF2 | c.3379G>C p.D1127H | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SLFN5 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- SPESP1 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPG11 | c.1793A>T p.Y598F | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SPSB4 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SPTA1 | c.2994G>A p.M998I | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2
- SRSF6 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 47/626 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.089); called by muse, mutect2
- STAM | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SUFU | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.028); called by muse, mutect2
- SV2A | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- SVEP1 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE1 | c.12237C>G p.F4079L (on ENST00000367255 / NM_182961.4; = p.F4008L on NM_033071.3) | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.114); called by muse, mutect2
- SYT16 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 32/801 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- SYT4 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 12/404 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.086); called by muse, mutect2
- TAF1 | c.625C>A p.L209I (on ENST00000373790 / NM_138923.4; = p.L230I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- TAS2R40 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TDRD10 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); called by muse, mutect2
- TEX13C | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 40/525 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TGFBI | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TKTL1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 27/311 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMEM132C | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 59/628 reads (9%) | called by muse, mutect2
- TMTC1 | c.1904C>G p.A635G (on ENST00000539277 / NM_001193451.2; = p.A527G on NM_175861.3) | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMTC1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by mutect2, varscan2
- TNFAIP2 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 38/572 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOM1L1 | c.59-8C>G | Splice Region (SNP) | VAF 32/750 reads (4%) | called by muse, mutect2
- TRBV7-1 | c.142C>G p.H48D | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM49B | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); called by muse, mutect2
- TRPM8 | c.3134T>A p.F1045Y | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2
- TRUB1 | c.422G>T p.S141I | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.166); called by muse, mutect2
- TSPAN14 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 38/617 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- TSR3 | c.704-1G>C p.X235_splice | Splice Site (SNP) | VAF 28/430 reads (7%) | called by muse, mutect2
- TTN | c.8031C>G p.I2677M (on ENST00000591111; = p.I2631M on NM_003319.4) | Missense Mutation (SNP) | VAF 36/635 reads (6%) | PolyPhen benign (0.255); called by muse, mutect2
- UCP2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC5C | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 41/620 reads (7%) | called by muse, mutect2
- USP43 | c.2238G>T p.R746S | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- VPS13B | c.10088C>G p.T3363S | Missense Mutation (SNP) | VAF 58/813 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- VPS51 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2
- VWA7 | c.1424C>G p.S475* | Nonsense Mutation (SNP) | VAF 46/538 reads (9%) | called by muse, mutect2
- WDFY3 | c.4296G>T p.K1432N | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XIAP | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZC3H18 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 33/485 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ZDBF2 | c.3359C>T p.P1120L | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- ZDHHC9 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 80/717 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZFHX4 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ZFP82 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZMYM3 | c.1562G>T p.S521I | Missense Mutation (SNP) | VAF 37/496 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2
- ZNF333 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ZNF529 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- ZNF674 | c.985A>C p.T329P | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- ZNF711 | c.2248C>T p.Q750* | Nonsense Mutation (SNP) | VAF 38/414 reads (9%) | called by muse, mutect2
- ZNF786 | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
- ZXDA | c.1612G>A p.V538M | Missense Mutation (SNP) | VAF 32/774 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- ABCA6 | c.4110G>C p.T1370= | Silent (SNP) | VAF 35/450 reads (8%) | called by muse, mutect2
- ADCY6 | c.660G>T p.A220= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV57170940; called by muse, mutect2, varscan2
- ADGRE2 | c.2037A>G p.Q679= | Silent (SNP) | VAF 84/471 reads (18%) | catalogued as rs370665322; called by muse, mutect2, varscan2
- ADGRG4 | c.8550C>A p.I2850= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- ADRB1 | c.288C>T p.F96= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- AL136295.1 | c.1791C>T p.F597= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, varscan2
- ALX1 | c.307C>A p.R103= | Silent (SNP) | VAF 41/326 reads (13%) | catalogued as COSV100374319, COSV57492423; called by muse, mutect2, varscan2
- AP5Z1 | c.1986C>T p.C662= | Silent (SNP) | VAF 38/338 reads (11%) | catalogued as rs771961451; called by muse, mutect2, varscan2
- APOE | c.408C>T p.Y136= | Silent (SNP) | VAF 85/406 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.2184C>T p.I728= | Silent (SNP) | VAF 27/411 reads (7%) | called by muse, mutect2
- ARMH1 | c.39C>G p.L13= | Silent (SNP) | VAF 68/612 reads (11%) | called by muse, mutect2, varscan2
- ASMT | c.981A>G p.R327= (on ENST00000381229; = p.R355= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/955 reads (8%) | called by muse, mutect2
- ATP6V0A1 | c.996C>T p.S332= | Silent (SNP) | VAF 78/520 reads (15%) | catalogued as COSV52873102; called by muse, mutect2, varscan2
- CATSPERG | c.2034G>T p.S678= | Silent (SNP) | VAF 36/304 reads (12%) | catalogued as COSV53051204; called by muse, mutect2, varscan2
- CDH12 | c.58C>T p.L20= | Silent (SNP) | VAF 40/571 reads (7%) | catalogued as COSV101203450; called by muse, mutect2
- CDKL5 | c.2397T>A p.P799= | Silent (SNP) | VAF 81/871 reads (9%) | catalogued as COSV66112457; called by muse, mutect2
- CEP76 | c.1431C>G p.T477= | Silent (SNP) | VAF 49/472 reads (10%) | called by muse, mutect2, varscan2
- CHRM3 | c.1284C>T p.P428= | Silent (SNP) | VAF 56/736 reads (8%) | called by muse, mutect2
- COPS8 | c.390C>T p.A130= | Silent (SNP) | VAF 35/493 reads (7%) | catalogued as rs533865440; called by muse, mutect2
- CRACDL | c.1800C>T p.L600= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV67409790; called by muse, mutect2, varscan2
- DDX17 | c.1443G>T p.G481= | Silent (SNP) | VAF 8/201 reads (4%) | called by muse, mutect2
- DDX23 | c.1695G>A p.K565= | Silent (SNP) | VAF 66/1114 reads (6%) | catalogued as rs1244519275, COSV99974993; called by muse, mutect2
- DGCR2 | c.1077C>A p.L359= | Silent (SNP) | VAF 34/345 reads (10%) | called by muse, mutect2
- DMBT1 | c.1551C>T p.T517= | Silent (SNP) | VAF 41/800 reads (5%) | catalogued as rs371686981; called by muse, mutect2
- DMRTB1 | c.807G>T p.P269= | Silent (SNP) | VAF 28/254 reads (11%) | catalogued as COSV101008378; called by muse, varscan2
- DMRTC2 | c.903G>A p.L301= | Silent (SNP) | VAF 28/321 reads (9%) | catalogued as COSV99523478; called by muse, mutect2
- DNAH10 | c.9345G>A p.L3115= (on ENST00000409039; = p.L3054= on NM_207437.3) | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, varscan2
- DNAH14 | c.1311C>T p.L437= (on ENST00000445597; = p.L418= on NM_001145154.3) | Silent (SNP) | VAF 16/406 reads (4%) | called by muse, mutect2
- DNAH3 | c.11940T>A p.S3980= | Silent (SNP) | VAF 65/488 reads (13%) | called by muse, mutect2, varscan2
- DNAH7 | c.7101C>T p.I2367= | Silent (SNP) | VAF 22/318 reads (7%) | catalogued as COSV100414222, COSV56778526; called by muse, mutect2
- DOCK3 | c.1737T>A p.P579= | Silent (SNP) | VAF 34/383 reads (9%) | called by muse, mutect2
- DSCAM | c.1836G>T p.R612= | Silent (SNP) | VAF 62/391 reads (16%) | called by muse, mutect2, varscan2
- EHD3 | c.195C>T p.G65= | Silent (SNP) | VAF 64/494 reads (13%) | called by muse, mutect2, varscan2
- EHMT2 | c.3632G>A p.*1211= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- EIF2B1 | c.405G>C p.L135= | Silent (SNP) | VAF 55/839 reads (7%) | called by muse, mutect2
- ENDOD1 | c.1224C>T p.V408= | Silent (SNP) | VAF 31/704 reads (4%) | called by muse, mutect2
- EPHB1 | c.1764C>A p.S588= | Silent (SNP) | VAF 34/319 reads (11%) | called by muse, mutect2, varscan2
- ERGIC2 | c.1101C>T p.N367= | Silent (SNP) | VAF 48/609 reads (8%) | called by muse, mutect2
- ERN1 | c.711G>C p.L237= | Silent (SNP) | VAF 117/1283 reads (9%) | called by muse, mutect2
- FAM171A1 | c.2322G>A p.Q774= | Silent (SNP) | VAF 20/247 reads (8%) | catalogued as COSV65317031; called by muse, mutect2
- FAM71F1 | c.975C>T p.L325= | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- FANK1 | c.588C>G p.L196= | Silent (SNP) | VAF 28/398 reads (7%) | called by muse, mutect2
- FASN | c.1596G>C p.L532= | Silent (SNP) | VAF 32/653 reads (5%) | catalogued as COSV60752175; called by muse, mutect2
- FAT2 | c.6381C>G p.L2127= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- FCRL3 | c.741C>A p.I247= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs1193622845, COSV63843714, COSV63844784; called by muse, mutect2, varscan2
- FOXJ1 | c.294G>C p.R98= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV53948520, COSV99487316; called by muse, mutect2
- FRMD6 | c.873A>T p.P291= (on ENST00000344768 / NM_001267046.2; = p.P283= on NM_152330.4) | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- FRMPD1 | c.4233G>C p.L1411= | Silent (SNP) | VAF 36/447 reads (8%) | catalogued as COSV66703437; called by muse, mutect2
- FYB1 | c.1032G>A p.Q344= | Silent (SNP) | VAF 30/554 reads (5%) | catalogued as COSV60949068; called by muse, mutect2
- GLI1 | c.1213C>A p.R405= | Silent (SNP) | VAF 40/525 reads (8%) | catalogued as COSV57366679, COSV99953804; called by muse, mutect2
- GRIN3A | c.600C>A p.P200= | Silent (SNP) | VAF 37/354 reads (10%) | catalogued as COSV62458971; called by muse, mutect2, varscan2
- GRIP2 | c.70T>C p.L24= | Silent (SNP) | VAF 29/782 reads (4%) | catalogued as rs1204447981; called by muse, mutect2
- HECTD1 | c.1218T>C p.F406= | Silent (SNP) | VAF 23/217 reads (11%) | called by muse, mutect2, varscan2
- HGH1 | c.339G>T p.A113= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- ITPR1 | c.5634C>T p.N1878= (on ENST00000354582; = p.N1823= on NM_002222.7) | Silent (SNP) | VAF 20/213 reads (9%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2688C>T p.F896= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV58025900; called by muse, mutect2, varscan2
- KCNJ14 | c.417C>T p.L139= | Silent (SNP) | VAF 40/271 reads (15%) | called by muse, mutect2, varscan2
- KCNK9 | c.93G>A p.S31= | Silent (SNP) | VAF 30/726 reads (4%) | catalogued as COSV100271612; called by muse, mutect2
- KLHL34 | c.498G>A p.A166= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1398661032; called by muse, mutect2, varscan2
- KLHL4 | c.1821T>G p.R607= | Silent (SNP) | VAF 28/306 reads (9%) | called by muse, mutect2
- KMT2D | c.9405C>T p.T3135= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs376141976; called by muse, mutect2
- KPNA1 | c.1212C>T p.I404= | Silent (SNP) | VAF 34/314 reads (11%) | called by muse, mutect2
- LRRC25 | c.357C>A p.A119= | Silent (SNP) | VAF 44/257 reads (17%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1449G>T p.L483= | Silent (SNP) | VAF 36/375 reads (10%) | called by muse, mutect2
- MED12 | c.5835T>A p.T1945= | Silent (SNP) | VAF 49/641 reads (8%) | called by muse, mutect2
- MROH5 | c.579G>C p.L193= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- MYH15 | c.3276G>A p.L1092= | Silent (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- MYLK | c.2202G>A p.L734= | Silent (SNP) | VAF 50/412 reads (12%) | catalogued as rs1560108452; called by muse, mutect2, varscan2
- NBPF11 | c.918C>T p.F306= | Silent (SNP) | VAF 38/1348 reads (3%) | called by muse, mutect2
- NCAM1 | c.2019C>A p.S673= (on ENST00000316851 / NM_181351.5; = p.S663= on NM_000615.7) | Silent (SNP) | VAF 42/395 reads (11%) | called by muse, mutect2, varscan2
- NDOR1 | c.747G>A p.L249= | Silent (SNP) | VAF 32/338 reads (9%) | catalogued as COSV61287651; called by muse, mutect2
- NLRP12 | c.3165T>A p.P1055= | Silent (SNP) | VAF 177/1079 reads (16%) | called by muse, mutect2, varscan2
- OR10A3 | c.342C>A p.L114= | Silent (SNP) | VAF 40/450 reads (9%) | catalogued as COSV62459806; called by muse, mutect2
- OR10W1 | c.420C>G p.V140= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- OR2B11 | c.93C>A p.L31= | Silent (SNP) | VAF 56/696 reads (8%) | called by muse, mutect2
- OR51A7 | c.588C>T p.V196= | Silent (SNP) | VAF 32/454 reads (7%) | catalogued as rs374525532; called by muse, mutect2
- OR6V1 | c.24C>T p.S8= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as rs369508746; called by muse, mutect2, varscan2
- PAX3 | c.667C>A p.R223= | Silent (SNP) | VAF 118/794 reads (15%) | catalogued as CM941141, COSV100399333; called by muse, varscan2
- PCDH7 | c.1962C>A p.P654= | Silent (SNP) | VAF 38/328 reads (12%) | called by muse, varscan2
- PCDHB8 | c.1371C>T p.Y457= | Silent (SNP) | VAF 68/978 reads (7%) | called by muse, mutect2
- PDE1C | c.225G>T p.V75= | Silent (SNP) | VAF 50/309 reads (16%) | called by muse, mutect2, varscan2
- PHKB | c.2787G>A p.Q929= | Silent (SNP) | VAF 60/848 reads (7%) | called by muse, mutect2
- PLRG1 | c.951G>A p.V317= | Silent (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- POTEF | c.2724C>A p.I908= | Silent (SNP) | VAF 29/567 reads (5%) | catalogued as COSV100664655, COSV62545303; called by muse, mutect2
- PTPN12 | c.1173A>T p.P391= | Silent (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- RTL1 | c.1146C>A p.I382= | Silent (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- RYR3 | c.11430G>A p.Q3810= (on ENST00000389232; = p.Q3811= on NM_001036.6) | Silent (SNP) | VAF 10/201 reads (5%) | catalogued as COSV104430513; called by muse, mutect2
- SBF2 | c.2925A>G p.A975= | Silent (SNP) | VAF 36/482 reads (7%) | catalogued as rs749576038; called by muse, mutect2
- SEC31B | c.3501G>A p.L1167= | Silent (SNP) | VAF 20/430 reads (5%) | catalogued as rs1392049462, COSV59325351; called by muse, mutect2
- SEMA5A | c.1117C>T p.L373= | Silent (SNP) | VAF 38/709 reads (5%) | catalogued as rs1481314681, COSV66785473; called by muse, mutect2
- SEPTIN14 | c.480G>T p.V160= | Silent (SNP) | VAF 28/330 reads (8%) | called by muse, mutect2
- SERPINB3 | c.267G>A p.L89= | Silent (SNP) | VAF 36/637 reads (6%) | called by muse, mutect2
- SHPRH | c.1158G>C p.L386= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- SIGLEC6 | c.453C>T p.S151= | Silent (SNP) | VAF 59/635 reads (9%) | called by muse, mutect2
- SLAIN1 | c.960A>G p.Q320= (on ENST00000466548; = p.Q57= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/426 reads (12%) | called by muse, mutect2, varscan2
- SLC14A2 | c.2709G>A p.E903= | Silent (SNP) | VAF 49/772 reads (6%) | called by muse, mutect2
- SLC9A7 | c.1332C>T p.F444= | Silent (SNP) | VAF 32/422 reads (8%) | catalogued as COSV100091591; called by muse, mutect2
- SLCO5A1 | c.2394C>T p.F798= | Silent (SNP) | VAF 40/495 reads (8%) | catalogued as COSV52661353; called by muse, mutect2
- SLITRK5 | c.2016G>T p.L672= | Silent (SNP) | VAF 57/448 reads (13%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4221C>G p.L1407= | Silent (SNP) | VAF 60/542 reads (11%) | catalogued as rs1021653440; called by muse, mutect2, varscan2
- SNTG1 | c.1530G>T p.T510= | Silent (SNP) | VAF 20/203 reads (10%) | catalogued as COSV52452519; called by muse, mutect2
- SPIN4 | c.85C>A p.R29= | Silent (SNP) | VAF 15/308 reads (5%) | called by muse, mutect2
- SRP72 | c.27G>T p.V9= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- SRSF8 | c.732C>T p.S244= | Silent (SNP) | VAF 46/682 reads (7%) | catalogued as rs781816863; called by muse, mutect2
- STK17A | c.156C>G p.T52= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs986970386; called by muse, mutect2
- SUV39H1 | c.472C>A p.R158= | Silent (SNP) | VAF 34/412 reads (8%) | catalogued as rs1457998837, COSV100551735; called by muse, mutect2
- SVEP1 | c.978G>T p.G326= | Silent (SNP) | VAF 31/313 reads (10%) | called by muse, mutect2, varscan2
- TAS1R2 | c.1251C>T p.P417= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.210C>T p.I70= | Silent (SNP) | VAF 8/207 reads (4%) | called by muse, mutect2
- TRABD2A | c.1284G>T p.R428= (on ENST00000409520 / NM_001277053.2; = p.R379= on NM_001080824.3) | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV52862068; called by muse, mutect2
- TRAV12-3 | c.165C>T p.F55= | Silent (SNP) | VAF 18/364 reads (5%) | catalogued as rs1158023491; called by muse, mutect2
- TRHDE | c.246C>T p.G82= | Silent (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- TRPM6 | c.1701C>T p.F567= | Silent (SNP) | VAF 34/688 reads (5%) | called by muse, mutect2
- TTLL7 | c.2337C>T p.G779= | Silent (SNP) | VAF 21/242 reads (9%) | called by muse, mutect2
- TTN | c.12420C>T p.I4140= (on ENST00000591111; = p.I4094= on NM_003319.4) | Silent (SNP) | VAF 25/391 reads (6%) | catalogued as rs570991398, COSV60397446; ClinVar: likely benign; called by muse, mutect2
- UMPS | c.1269A>T p.A423= | Silent (SNP) | VAF 44/402 reads (11%) | called by muse, mutect2, varscan2
- USH2A | c.7527G>T p.R2509= | Silent (SNP) | VAF 34/432 reads (8%) | catalogued as rs575939496; ClinVar: uncertain significance; called by muse, mutect2
- VAV2 | c.360C>T p.I120= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs928990590; called by muse, mutect2
- VSTM5 | c.153C>A p.I51= | Silent (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- WT1 | c.711C>A p.P237= | Silent (SNP) | VAF 57/508 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.7866C>G p.L2622= (on ENST00000628543; = p.L2797= on NM_152381.6) | Silent (SNP) | VAF 20/284 reads (7%) | catalogued as COSV54679932; called by muse, mutect2
- XKR7 | c.1362C>A p.I454= | Silent (SNP) | VAF 24/222 reads (11%) | called by muse, mutect2
- ZBTB3 | c.1182C>G p.P394= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as rs761971879, COSV67360887; called by muse, mutect2
- ZBTB49 | c.1701C>A p.I567= | Silent (SNP) | VAF 38/716 reads (5%) | called by muse, mutect2
- ZC3H18 | c.264G>C p.L88= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs772761564, COSV56322470; called by mutect2, varscan2
- ZDHHC8 | c.1536G>T p.G512= | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, varscan2
- ZGPAT | c.141C>T p.I47= | Silent (SNP) | VAF 21/266 reads (8%) | catalogued as COSV60831748; called by muse, mutect2
- ZNF101 | c.1206C>G p.V402= | Silent (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- ZNF703 | c.135G>A p.A45= | Silent (SNP) | VAF 50/462 reads (11%) | catalogued as COSV58998620; called by muse, mutect2
- AL132655.6 | chr20:58840169 C>A | 5'Flank (SNP) | VAF 26/244 reads (11%) | called by muse, mutect2, varscan2
- AL352984.1 | n.90G>A | RNA (SNP) | VAF 39/330 reads (12%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827546 G>A | 3'Flank (SNP) | VAF 72/1205 reads (6%) | catalogued as rs1264995342; called by muse, mutect2
- ANKRD20A8P | n.732G>A | RNA (SNP) | VAF 18/521 reads (3%) | called by muse, mutect2
- AP001993.1 | n.3385T>A | RNA (SNP) | VAF 29/403 reads (7%) | called by muse, mutect2
- ASIC1 | c.559-186G>T | Intron (SNP) | VAF 71/565 reads (13%) | called by muse, mutect2, varscan2
- ATP13A4 | c.*31G>C | 3'UTR (SNP) | VAF 15/123 reads (12%) | catalogued as COSV100710375; called by muse, mutect2, varscan2
- AVIL | c.1195-174C>T | Intron (SNP) | VAF 28/547 reads (5%) | called by muse, mutect2
- CALM3 | chr19:46600936 G>A | 5'Flank (SNP) | VAF 21/391 reads (5%) | called by muse, mutect2
- CAMTA1 | c.234+62449C>T | Intron (SNP) | VAF 38/348 reads (11%) | catalogued as rs1477186735; called by muse, mutect2, varscan2
- CTSLP8 | n.756C>T | RNA (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- DCHS2 | n.527G>T | RNA (SNP) | VAF 38/588 reads (6%) | called by muse, mutect2
- ELOVL5 | c.58+1172G>C | Intron (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- EVI5L | c.1200+1004G>A | Intron (SNP) | VAF 36/437 reads (8%) | called by muse, mutect2
- FBF1 | c.31+1931G>A | Intron (SNP) | VAF 46/514 reads (9%) | called by muse, mutect2
- FMO6P | n.1855C>A | RNA (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- GDI1 | c.388+39G>T | Intron (SNP) | VAF 18/212 reads (8%) | catalogued as COSV63895427; called by muse, mutect2
- GRHPR | c.734+147C>G | Intron (SNP) | VAF 40/714 reads (6%) | catalogued as COSV58942007; called by muse, mutect2
- GSDMD | c.-58C>T | 5'UTR (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- LEPR | c.-159G>T | 5'UTR (SNP) | VAF 26/257 reads (10%) | called by muse, mutect2
- LINC00671 | n.575C>A | RNA (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2
- LINC01148 | n.490C>A | RNA (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- MFNG | c.305-24C>T | Intron (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- MSR1 | c.-5+6401C>G | Intron (SNP) | VAF 20/309 reads (6%) | called by muse, mutect2
- MYCL | c.-338C>T | 5'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- NCOR1P1 | n.312C>T | RNA (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- PGK1 | c.1115-33C>G | Intron (SNP) | VAF 45/362 reads (12%) | catalogued as COSV59371137; called by muse, mutect2, varscan2
- REEP1 | c.-20C>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as rs1305609863; called by muse, mutect2, varscan2
- RPL35 | c.-37C>T | 5'UTR (SNP) | VAF 16/150 reads (11%) | catalogued as rs752476248; called by muse, mutect2, varscan2
- SLC35E2A | n.1032G>C | RNA (SNP) | VAF 48/828 reads (6%) | called by muse, mutect2
- SPATA31C1 | n.1826C>G | RNA (SNP) | VAF 49/623 reads (8%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1982G>C | RNA (SNP) | VAF 83/1105 reads (8%) | called by muse, mutect2
- SRPK1 | c.74+345G>C | Intron (SNP) | VAF 44/779 reads (6%) | called by muse, mutect2
- SSPOP | n.3821C>T | RNA (SNP) | VAF 11/150 reads (7%) | catalogued as rs1216655612; called by muse, mutect2
- STXBP2 | c.247-49G>C | Intron (SNP) | VAF 22/327 reads (7%) | called by muse, mutect2
- SVIL2P | n.2156C>A | RNA (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- TBATA | c.*22G>T | 3'UTR (SNP) | VAF 35/554 reads (6%) | called by muse, mutect2
- TCFL5 | c.1381-3873G>T | Intron (SNP) | VAF 74/721 reads (10%) | called by muse, mutect2
- TGFBR3 | c.*2730G>A | 3'UTR (SNP) | VAF 83/1130 reads (7%) | called by muse, mutect2
- TRAK1 | c.287-16414T>C | Intron (SNP) | VAF 34/358 reads (9%) | called by muse, mutect2, varscan2
- TRAV1-1 | c.-63C>T | 5'UTR (SNP) | VAF 38/605 reads (6%) | called by muse, mutect2
- XIAP | c.*581A>G | 3'UTR (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- XPO6 | c.3276+42G>C | Intron (SNP) | VAF 40/605 reads (7%) | called by muse, mutect2
- Y_RNA | chr7:75516198 A>G | 5'Flank (SNP) | VAF 59/758 reads (8%) | catalogued as rs782060070; called by muse, mutect2
- ZNF971P | n.919C>A | RNA (SNP) | VAF 41/432 reads (9%) | called by muse, mutect2
